Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A1QH, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A1QH-01A (Primary Tumor).

[page 1 of 4]
HIS/PA Discrepancy		☒

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

100-0-3 Carcinoma, papillary tall cell 8344/3
site: thyroid, NOS C 73.9 for 3/16/11

Clinical Diagnosis & History:

year old female with history of toxic goiter questionable UCO IB1, now with dominant right nodule; biopsy positive for papillary carcinoma.

Specimens Submitted:

- 1: SP: Lymph node, delphian, excision (fs)
- 2: SP: Lymph node, left paratrachea, excision (fs)
- 3: SP: Thyroid, total thyroidectomy
- 4: SP: Pretracheal tissue, excision
- 5: SP: Left supramediastinal tissue, excision

DIAGNOSIS:

1. SP: Lymph node, delphian, excision (fs):

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 2
Number of lymph nodes with metastatic disease: 2
Size of the largest lymph node involved by tumor: 0.6cm.
Size of the largest metastatic focus : 0.4 cm.
Extranodal extension is not identified

UUID:387740C3-B978-4F9B-A971-S6A6E8F170E6

2. SP: Lymph node, left paratrachea, excision (fs):

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 1
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 1cm.
Size of the largest metastatic focus : 0.6 cm.
Extranodal extension is not identified

3. SP: Thyroid, total thyroidectomy:

Tumor Type:

Papillary carcinoma, tall cell variant

Mitotic Activity:

Mild to moderate

Tumor Necrosis:

Not identified

Other Tumor Features:

Psammoma bodies

[page 2 of 4]
Tumor Location:
Both lobes and isthmus

Tumor Size:
The tumor spans the entire thyroid and is at least 7 cm

Tumor Encapsulation:
None identified

Blood Vessel Invasion:
Not identified

Extrathyroid Extension:
There is extensive extension into peri-thyroidal fibroadipose tissue and skeletal muscle

Surgical Margins:
Tumor is at the posterior margin

Non-Neoplastic Thyroid:
shows changes consistent with previous radioactive iodine administration

Parathyroid Glands:
One parathyroid gland involved by thyroid carcinoma

Lymph Nodes:
Perinodal (extracapsular) extension identified
Metastatic carcinoma in 4 of 4 lymph nodes (4/4)

4. SP: Pretracheal tissue, excision:

Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 1

5. SP: Left supramediastinal tissue, excision:

Benign thymus
One unremarkable parathyroid gland.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh for frozen section consultation, labeled "Delphian node" and consists of two lymph nodes measuring in aggregate 0.9 x 0.8 x 0.4 cm. The specimen is entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

2. The specimen is received fresh for frozen section consultation, labeled "left paratracheal lymph node" and consists of a lymph node measuring 1x 1 x 0.6 cm. The specimen is bisected and entirely submitted for frozen section.

[page 3 of 4]
3). The specimen is received fresh, labeled "Total thyroidectomy stitch marks right lobe of thyroid" and consists of a thyroid weighing 50 g. The right lobe measures 4 x 4 x 4 cm, the left lobe measures 3 x 1.5 x 1.5 cm and the isthmus measures 0.3 x 0.3 x 0.2 cm. Both lobes appear to be matted by small amount of isthmus. The external surface is covered by a thin fibrous capsule, and attached pink tan soft tissue. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 4 x 4 x 4 white-tan nodule with attached matted 1 x 1 x 1 cystic nodule, located on the right lobe abutting the capsular margin and abutting the left lobe which shows a 2.5 x 2 x 2 cm nodule extended to all parenchyma. Sections through the remaining tissue reveal predominantly white tan firm cut surface extended to the all specimen parenchyma. Representative sections of the specimen are submitted for _____ and a photograph has been taken. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

RL - right lobe
LL - left lobe
IS - isthmus

4). The specimen is received in formalin, labeled "Pretracheal tissue" and consists of a 0.3 x 0.3 x 0.2 cm pink-tan irregular portion of soft tissue. The specimen is entirely submitted.

Summary of sections:

U-- undesignated

5). The specimen is received in formalin, labeled "Left supramediastinal tissue" and consists of a 2.0 x 1.0 x 0.3 cm portion of yellow lobulated tissue. No lymph nodes are grossly identified. The entire specimen submitted.

Summary of sections:

U-- undesignated

Summary of Sections:

Part 1: SP: Lymph node, delphian, excision (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: SP: Lymph node, left paratrachea, excision (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 3: SP: Thyroid, total thyroidectomy

Block	Sect. Site	PCs
1	IS	1
6	LL	6
19	RL	19

Part 4: SP: Pretracheal tissue, excision

Block	Sect. Site	PCs
1	U	1

Part 5: SP: Left supramediastinal tissue, excision

Block	Sect. Site	PCs
1	U	1

[page 4 of 4]
Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: DELPHIAN NODE (FS): METASTATIC PAPILLARY CARCINOMA IN TWO OF TWO LYMPH NODES (2/2)
PERMANENT DIAGNOSIS: SAME

2. FROZEN SECTION DIAGNOSIS: SP: LEFT PARATRACHEAL NODE (FS): METASTATIC PAPILLARY CARCINOMA
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file c766012e-043a-4613-a47c-5f8895e41039 (TCGA-DJ-A1QH.387740C3-B978-4F9B-A971-56A6E8F170E6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).